Gene-level copy-number profile of tumor specimen TCGA-29-1710-02A from TCGA case TCGA-29-1710, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 54.7 years (19,969 days).
Specimen TCGA-29-1710-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.9f89fea0-54eb-4954-8ea4-d0c87631d40f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1710-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 403 have no estimate.
https://portal.gdc.cancer.gov/files/21a87805-7eb7-4ae0-88c0-79d1fa311816

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 525; copy number 1: 1,070; copy number 2: 16,901; copy number 3: 28,190; copy number 4: 7,099; copy number 5: 2,812; copy number 6: 2,337; copy number 7: 811; copy number 8: 276; copy number 9: 98; copy number 10: 24; copy number 12: 32; copy number 15: 8; copy number 20: 37.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,286 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:202,122,917–202,189,455, 4 genes, copy number 7: GPR37L1, ARL8A, PTPN7, PTPRVP.
- chr1:214,051,194–248,919,946, 759 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr2:88,811,186–88,861,563, 1 gene, copy number 12 (within-gene range 4–12): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 12: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr3:108,032,456–117,139,389, 139 genes, copy number 7–8 (within-gene range 0–8) (broad region; genes not listed).
- chr3:158,696,892–158,732,489, 1 gene, copy number 7 (within-gene range 5–7): RARRES1.
- chr6:57,029,521–57,222,307, 6 genes, copy number 10: MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23.
- chr6:57,390,132–57,390,212, 1 gene, copy number 10: MIR548U.
- chr8:121,954,640–125,091,819, 77 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr8:126,325,454–129,683,770, 39 genes, copy number 7–12 (within-gene range 3–12): AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1.
- chr19:18,907,013–20,321,305, 74 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr19:27,638,483–30,957,192, 69 genes, copy number 9–20 (broad region; genes not listed).
- chr19:33,283,978–33,285,739, 1 gene, copy number 8: AC008738.6.
- chr19:35,432,957–36,173,853, 65 genes, copy number 9 (broad region; genes not listed).
- chr19:55,769,118–56,185,775, 14 genes, copy number 9: RFPL4AL1, RFPL4AP1, NLRP11, NLRP4, NLRP13, NLRP8, NLRP5, LINC01864, ZNF787, Y_RNA, AC024580.2, ZNF444, AC024580.1, GALP.
- chr19:56,439,325–56,626,481, 12 genes, copy number 9 (within-gene range 2–9): ZNF667, ZNF667-AS1, AC004696.2, AC004696.1, ZNF471, AC005498.1, AC005498.2, ZFP28, AC005498.3, ZNF470, SIGLEC31P, ZNF71.

Autosomal genes at a single copy (total copy number 1): 160. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
